Somatic mutation profile of tumor specimen C3N-00320-04 (aliquot CPT0012390009) from CPTAC case C3N-00320, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.3 years (24,594 days).
Specimen C3N-00320-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8145a69-998e-4209-945a-6f29d998dd38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00320-31 (Blood Derived Normal), aliquot CPT0012530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/854e3d6f-aeff-4f89-8f22-7fb68da37ce2

The open-access MAF lists 124 somatic variants for this specimen: 86 protein-altering or splice-affecting, 25 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 25, Intron 9, Frame Shift Del 8, In Frame Del 5, Nonsense Mutation 5, Splice Site 2, 3'UTR 2, 5'UTR 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4447T>C p.C1483R | Missense Mutation (SNP) | VAF 31/80 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1057519914, COSV63875155; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NOTCH3 | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs28937321, CM961042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.340+2T>A p.X114_splice | Splice Site (SNP) | VAF 129/224 reads (58%) | hotspot (GDC flag); catalogued as CD983001, COSV56547957, COSV56551654, COSV56551713, COSV56563827; called by muse, mutect2, varscan2
- ADGRA1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs755811625, COSV74142839; called by muse, mutect2, varscan2
- AL035078.4 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs749117053; called by muse, mutect2, varscan2
- ATP13A1 | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99366716; called by muse, mutect2, varscan2
- BECN1 | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV100831112; called by muse, mutect2, varscan2
- BICRA | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs1318644811, COSV67603580; called by muse, mutect2, varscan2
- COL24A1 | c.3325C>A p.P1109T | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV65313975; called by muse, mutect2, varscan2
- FBLN1 | c.1225C>A p.R409S | Missense Mutation (SNP) | VAF 200/623 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1218807619; called by muse, mutect2, varscan2
- IQGAP3 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs749818611; called by muse, mutect2, varscan2
- MAN2B2 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs757830667, COSV53450411, COSV99577991; called by muse, mutect2, varscan2
- PCDH7 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688654; called by muse, mutect2, varscan2
- PDE8B | c.2185A>G p.M729V | Missense Mutation (SNP) | VAF 109/385 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs757855600; called by muse, mutect2, varscan2
- PPA2 | c.736G>A p.G246R (on ENST00000341695 / NM_176869.3; = p.G217R on NM_006903.4) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58996125; called by muse, mutect2
- PRKG1 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773713867; called by muse, mutect2, varscan2
- PRPF40B | c.2053-4C>G | Splice Region (SNP) | VAF 41/148 reads (28%) | catalogued as rs1460701180; called by muse, mutect2, varscan2
- RABEP2 | c.555del p.H186Mfs*28 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | catalogued as COSV100706746; called by mutect2, pindel, varscan2
- UGT1A7 | c.671dup p.K225Qfs*9 | Frame Shift Ins (INS) | VAF 73/296 reads (25%) | catalogued as rs1476036720; called by mutect2, pindel, varscan2
- VARS1 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763964925, COSV65155616; called by muse, mutect2, varscan2
- ZNF541 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 121/440 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV54545132; called by muse, mutect2, varscan2
- ACTL8 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- ACTR3C | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 96/241 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- AK4 | c.355_357del p.L119del | In Frame Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- AK7 | c.1455G>C p.K485N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ANKDD1A | c.1425_1433del p.E475_S478delinsD | In Frame Del (DEL) | VAF 36/246 reads (15%) | called by mutect2, pindel, varscan2
- APBB3 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- BMP2K | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- C2CD3 | c.3044G>A p.G1015E | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNB2 | c.1042A>G p.R348G (on ENST00000324631 / NM_201596.3; = p.R293G on NM_000724.4) | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CACNB2 | c.1043G>A p.R348K (on ENST00000324631 / NM_201596.3; = p.R293K on NM_000724.4) | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CAMKK1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAPS2 | c.1121del p.L374* | Frame Shift Del (DEL) | VAF 50/210 reads (24%) | called by pindel, varscan2
- CC2D1B | c.1724C>A p.A575D | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CCDC168 | c.9328C>A p.H3110N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC96 | c.973_978del p.K325_E326del | In Frame Del (DEL) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- CCL11 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELF2 | c.1043C>G p.T348S (on ENST00000416382 / NM_001025077.3; = p.T355S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLIP1 | c.2065G>T p.A689S (on ENST00000620786 / NM_001247997.1; = p.A678S on NM_002956.2) | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL4A2 | c.2959A>T p.K987* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- CR1 | c.3712C>A p.L1238M | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CRELD1 | c.501_503delinsT p.Q168Vfs*2 | Frame Shift Del (DEL) | VAF 22/129 reads (17%) | called by pindel, varscan2*
- CSMD1 | c.2720G>T p.S907I (on ENST00000520002; = p.S906I on NM_033225.6) | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DGCR2 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNM1P46 | n.469C>T | Splice Region (SNP) | VAF 29/242 reads (12%) | called by muse, mutect2
- DYNC1H1 | c.9835A>T p.K3279* | Nonsense Mutation (SNP) | VAF 55/194 reads (28%) | called by muse, mutect2
- ELP3 | c.1187T>A p.I396K | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHB3 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ERMAP | c.1214del p.N405Tfs*5 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | called by mutect2, pindel, varscan2
- GOLGA8H | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 199/660 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GRIN2D | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- HDHD5 | c.637C>G p.L213V (on ENST00000336737 / NM_033070.3; = p.L183V on NM_017829.5) | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- INTS14 | c.748+1G>A p.X250_splice (on ENST00000313182 / NM_001366360.2; = p.X171_splice on NM_001136043.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 27/81 reads (33%) | called by muse, varscan2
- KAT2A | c.2306T>C p.I769T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIN54 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC5B | c.7784C>A p.T2595N | Missense Mutation (SNP) | VAF 164/500 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MYH3 | c.2963A>T p.E988V | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MYH3 | c.2962G>T p.E988* | Nonsense Mutation (SNP) | VAF 55/169 reads (33%) | called by muse, mutect2, varscan2
- NELL2 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NEO1 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OPTN | c.49_51del p.S17del | In Frame Del (DEL) | VAF 89/333 reads (27%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1450A>T p.K484* | Nonsense Mutation (SNP) | VAF 40/83 reads (48%) | called by muse, varscan2
- PCDHGA10 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDE8B | c.445T>C p.W149R | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAD50 | c.3817_3821del p.F1273Gfs*7 | Frame Shift Del (DEL) | VAF 39/140 reads (28%) | called by mutect2, pindel, varscan2
- RECK | c.945T>A p.N315K | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RECK | c.1723A>T p.I575L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- SBNO2 | c.3546G>T p.M1182I | Missense Mutation (SNP) | VAF 40/568 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- SCAF4 | c.2341A>G p.I781V | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGCZ | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SLC35D2 | c.877del p.I293Ffs*5 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- SPIN3 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNGAP1 | c.2786A>T p.N929I | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TASOR2 | c.3746del p.N1249Ifs*2 | Frame Shift Del (DEL) | VAF 34/131 reads (26%) | called by mutect2, pindel, varscan2
- TBC1D12 | c.1283_1291del p.A428_R431delinsG | In Frame Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- TBC1D9 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THAP3 | c.381G>T p.M127I (on ENST00000054650 / NM_001195753.1; = p.M134I on NM_138350.3) | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMCO5A | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TOMM34 | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 51/147 reads (35%) | called by muse, mutect2, varscan2
- TTI2 | c.1139A>T p.H380L | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC80 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 123/428 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP28 | c.2470C>G p.R824G | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY3 | c.8669del p.F2890Sfs*14 | Frame Shift Del (DEL) | VAF 35/137 reads (26%) | called by mutect2, pindel, varscan2
- WIZ | c.4203G>T p.M1401I (on ENST00000673675 / NM_001371589.1; = p.M306I on NM_021241.3) | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ZC3H7A | c.1892A>T p.Q631L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ZNF724 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- CAMKK1 | c.1509T>A p.A503= | Silent (SNP) | VAF 60/218 reads (28%) | called by muse, mutect2, varscan2
- CEP76 | c.1401A>T p.G467= | Silent (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- COL24A1 | c.3324T>C p.I1108= | Silent (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- DLX6 | c.751C>T p.L251= | Silent (SNP) | VAF 157/525 reads (30%) | catalogued as rs1225120437; called by muse, mutect2, varscan2
- DQX1 | c.1123C>A p.R375= | Silent (SNP) | VAF 63/225 reads (28%) | catalogued as rs150420269; called by muse, mutect2, varscan2
- DYNC1H1 | c.9837A>G p.K3279= | Silent (SNP) | VAF 56/191 reads (29%) | called by muse, mutect2
- DYRK1A | c.816A>G p.A272= | Silent (SNP) | VAF 77/237 reads (32%) | catalogued as COSV100117899; called by muse, mutect2, varscan2
- EEF2KMT | c.993G>A p.*331= | Silent (SNP) | VAF 18/205 reads (9%) | catalogued as rs1337048855; called by muse, mutect2
- EPHB2 | c.1476G>A p.T492= | Silent (SNP) | VAF 145/433 reads (33%) | catalogued as rs370664820; called by muse, mutect2, varscan2
- FCGBP | c.4830G>T p.T1610= | Silent (SNP) | VAF 122/770 reads (16%) | called by muse, mutect2, varscan2
- ITGAD | c.1269C>T p.A423= | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as COSV66760153; called by muse, mutect2, varscan2
- KAT6A | c.4482C>T p.V1494= | Silent (SNP) | VAF 51/153 reads (33%) | catalogued as COSV55904223; called by muse, mutect2, varscan2
- KCNH5 | c.1923C>T p.I641= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as COSV59768828; called by muse, mutect2, varscan2
- LRP1B | c.5394C>T p.A1798= | Silent (SNP) | VAF 48/207 reads (23%) | catalogued as rs754226036; called by muse, mutect2, varscan2
- OR4C6 | c.651G>T p.T217= | Silent (SNP) | VAF 80/295 reads (27%) | catalogued as rs776795154, COSV58605361, COSV58606268; called by muse, mutect2, varscan2
- PRMT7 | c.1095G>T p.V365= | Silent (SNP) | VAF 117/344 reads (34%) | called by muse, mutect2, varscan2
- RBP3 | c.621C>T p.T207= | Silent (SNP) | VAF 202/421 reads (48%) | called by muse, mutect2, varscan2
- SIKE1 | c.549A>G p.L183= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs963804130; called by muse, mutect2, varscan2
- STAC2 | c.150G>A p.E50= | Silent (SNP) | VAF 79/266 reads (30%) | called by muse, mutect2, varscan2
- TCAF2 | c.2759A>G p.*920= (on ENST00000441159 / NM_001363538.2; = p.*816= on NM_001130026.2) | Silent (SNP) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- TCFL5 | c.744T>C p.A248= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- THBS1 | c.1428C>T p.G476= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as rs753944951; called by muse, mutect2, varscan2
- WTAP | c.996C>A p.L332= | Silent (SNP) | VAF 73/129 reads (57%) | called by muse, mutect2, varscan2
- ZBTB6 | c.627C>T p.D209= | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- ZNF616 | c.447T>A p.A149= | Silent (SNP) | VAF 48/117 reads (41%) | called by muse, mutect2, varscan2
- B4GALT4 | c.*325A>T | 3'UTR (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- CCT6A | c.-33A>G | 5'UTR (SNP) | VAF 50/230 reads (22%) | called by muse, mutect2, varscan2
- CFAP410 | c.643-236C>T | Intron (SNP) | VAF 77/234 reads (33%) | catalogued as rs748118167; called by muse, mutect2, varscan2
- FGFR3 | c.*755C>A | 3'UTR (SNP) | VAF 69/210 reads (33%) | called by muse, mutect2, varscan2
- FNTA | c.783-47del | Intron (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- FSD1L | c.441+43dup | Intron (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel
- IL12A | c.-25_-5del | 5'UTR (DEL) | VAF 53/305 reads (17%) | called by mutect2, pindel, varscan2
- KIF1B | c.2115+5993G>T | Intron (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+5994A>G | Intron (SNP) | VAF 28/134 reads (21%) | catalogued as rs376929489; called by muse, mutect2, varscan2
- MALRD1 | c.5030-2396G>T | Intron (SNP) | VAF 55/176 reads (31%) | called by muse, mutect2, varscan2
- NBAS | c.3257+539T>A | Intron (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- RHOQ | c.202-15459_202-15446del | Intron (DEL) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- SEPSECS | c.1211+37T>A | Intron (SNP) | VAF 49/159 reads (31%) | called by muse, mutect2, varscan2
